Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4804, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4804-01A (Primary Tumor).

[page 1 of 2]
Accession #:
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

1: SP: Kidney, right; partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with multiple foci of necrosis

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 5.1 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Peritumoral vascular invasion is identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal interstitial chronic inflammation and cortical cysts

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "right renal tumor". It consists of a 5.8 x 5.0 x 4.2 cm wedge shaped portion of kidney with a suture marking the deep margin and attached to 12.2 x 4.5 x 4.0 cm of attached perirenal fat. The margin is inked black, the perirenal fat is inked green and the specimen is serially sectioned to reveal a well-circumscribed hemorrhagic and focally cystic yellow-tan mass measuring 5.1 x 4.2 x 4.0 cm. The clearance from the resection margin is 0.2 cm. No gross extrarenal extension is identified. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS. Photographs are taken.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Add- Additional sections

Summary of Sections:

Part 1: SP: Kidney, right; partial nephrectomy

Block	Sect. Site	PCs
5	add	6
1	fsc	1
2	m	2
1	rs	1
4	t	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Right renal tumor (REDACTED): RENAL CORTICAL NEOPLASM, MARGIN NEGATIVE. (REDACTED)
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 928df47e-fec3-4ae4-bba8-73c51f23b3f5 (TCGA-BP-4804.8DF70566-2B2B-43C9-8761-FDBB31B93D96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).